TCGA case TCGA-V4-A9EV — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/da6f0ed2-a6d5-4d87-823e-122ebd59aaba

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 59 years; Year of birth: 1952; Vital status: Dead; Days to death: 1,269 days (3.5 years); Year of death: 2015; Cause of death: Cancer Related.

Diagnoses (2)
1. Mixed epithelioid and spindle cell melanoma (the primary disease): ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.8 years (21,855 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,269 days (3.5 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 20.
   Pathology details: Consistent pathology review: No; Epithelioid cell percent range: 31-60%; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: 31-60%; Tumor depth measurement: 13.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -9 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mixed epithelioid and spindle cell melanoma). Prior treatment: Yes.

Follow-up (6 entries)
- Days to follow up: 836 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,254 days (3.4 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,254 days (3.4 years).
- Days to follow up: 1,254 days (3.4 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 1,254 days (3.4 years).
- Days to follow up: 1,254 days (3.4 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,254 days (3.4 years).
- Days to follow up: 1,269 days (3.5 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 0.

Other clinical attributes
- Eye color: Blue.
- Comorbidities: Obesity.
- Timepoint category: Initial Diagnosis; Weight: 103 kg; Height: 152 cm; BMI: 44.6.

Exposures
- Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-V4-A9EV-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Spindle Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Metastatic Uveal Melanoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,269 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,269 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,269 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EV-01A-11D-A39V-01): tumor purity 0.75, ploidy 2.04, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- days to metastasis: 1254
- days to outcome: 21
- days to procedure 1: -9
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- outcome: Progressive Disease
- resection status 1: R0
- site of metastasis: liver, lung, cutaneous
- smoking status: smoker
- staging system: AJCC
- t stage: T4a
- test methodology: aCGH
- test result: high risk
- unresectable 1: no
